Somatic mutation profile of tumor specimen 0DWGJL from CCDI case PBCPAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 10.1 years (3,702 days).
Specimen 0DWGJL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 946d5e46-3ba6-4058-95cc-1eee45d9cc36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1bfd49a-277f-496a-9159-25ec83a73ca8

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/847 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- WSCD2 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 27/761 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.185); catalogued as COSV54587713; called by muse, mutect2
- ALG6 | c.1174G>T p.V392L | Missense Mutation (SNP) | VAF 34/1132 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2
- FRAS1 | c.11615A>G p.N3872S | Missense Mutation (SNP) | VAF 14/554 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- DBNL | c.597G>A p.E199= | Silent (SNP) | VAF 76/699 reads (11%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1038G>A p.A346= | Silent (SNP) | VAF 67/578 reads (12%) | catalogued as rs111362222; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTNG2 | c.-72G>A | 5'UTR (SNP) | VAF 7/166 reads (4%) | catalogued as rs935748298; called by muse, mutect2
